Somatic mutation profile of tumor specimen C3L-01155-01 (aliquot CPT0218890007) from CPTAC case C3L-01155, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,461 days).
Specimen C3L-01155-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ba51e4b-ec68-4849-890d-d366a96425b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01155-31 (Blood Derived Normal), aliquot CPT0220390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8922d7b-7d50-4e90-8b3e-945685977416

The open-access MAF lists 84 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 20, Intron 7, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 3, RNA 1, IGR 1, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 1782/9426 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- A4GALT | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.978); catalogued as rs758518911, COSV50747135; called by muse, mutect2, varscan2
- ARHGEF16 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 136/256 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs776739628, COSV65682983; called by muse, mutect2, varscan2
- CACNA1G | c.3569G>A p.R1190Q | Missense Mutation (SNP) | VAF 211/593 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs199761120; called by muse, mutect2, varscan2
- CALR3 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs1246411297; called by muse, mutect2, varscan2
- DNAJC3 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65132204; called by muse, mutect2
- EGFR | c.767A>C p.D256A | Missense Mutation (SNP) | VAF 263/9788 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51774829, COSV51792876; called by muse, mutect2
- EGR4 | c.1651G>A p.A551T (on ENST00000545030; = p.A448T on NM_001965.4) | Missense Mutation (SNP) | VAF 168/478 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71531932; called by muse, mutect2, varscan2
- FZD10 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as COSV57474645; called by muse, mutect2, varscan2
- IGHV4-59 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 112/451 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.712); catalogued as rs1240259784; called by muse, mutect2, varscan2
- KCNJ3 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54546671, COSV99715041; called by muse, mutect2, varscan2
- KMT2C | c.12194C>T p.A4065V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs141966811, COSV51437723; called by muse, mutect2, varscan2
- LBP | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs779213959; called by muse, mutect2, varscan2
- MATN4 | c.1567G>A p.V523M (on ENST00000372754; = p.V482M on NM_003833.4) | Missense Mutation (SNP) | VAF 120/422 reads (28%) | PolyPhen probably damaging (0.996); catalogued as rs748470059, COSV61352149; called by muse, mutect2, varscan2
- MUC12 | c.9800C>T p.T3267M (on ENST00000379442; = p.T3124M on NM_001164462.1) | Missense Mutation (SNP) | VAF 118/1847 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); catalogued as rs771151000; called by muse, mutect2
- OR2J3 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101013620, COSV65848752; called by muse, mutect2, varscan2
- OR56A4 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs374820484; called by muse, varscan2
- OTOG | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144060182; called by muse, mutect2, varscan2
- PALM | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 195/678 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs762171026; called by muse, mutect2, varscan2
- PCDHB14 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 78/537 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as rs1564001743; called by mutect2, varscan2
- POLR1B | c.3350G>A p.R1117Q | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs753674957; called by muse, mutect2, varscan2
- PROKR2 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 105/387 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs375036628, CM083841, COSV54086489; called by muse, mutect2, varscan2
- PTEN | c.46del p.Y16Ifs*8 | Frame Shift Del (DEL) | VAF 111/228 reads (49%) | catalogued as CM147225, COSV64294593; called by mutect2, pindel, varscan2
- RANBP6 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs771419317; called by muse, mutect2, varscan2
- RPL5 | c.189+1G>C p.X63_splice | Splice Site (SNP) | VAF 79/136 reads (58%) | catalogued as CS086169, CS100831, COSV59873155; called by muse, mutect2, varscan2
- ST14 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216979740; called by muse, mutect2, varscan2
- SVOPL | c.622G>A p.A208T (on ENST00000419765; = p.A56T on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1256191551, COSV55993640; called by muse, mutect2, varscan2
- TMEM71 | c.715C>G p.L239V (on ENST00000523829 / NM_001382398.1; = p.L220V on NM_144649.3) | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV63459614, COSV63459694; called by muse, mutect2, varscan2
- UBASH3A | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 180/527 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs775258006; called by muse, mutect2, varscan2
- ZNF568 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100451482; called by muse, mutect2, varscan2
- ZW10 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV52316489; called by muse, mutect2
- AHNAK2 | c.16708A>C p.T5570P | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- AMIGO3 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 404/1003 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASCC3 | c.5273_5276del p.Y1758Ffs*7 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | called by pindel, varscan2
- CHD3 | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRM2 | c.2018T>A p.F673Y | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- HS3ST4 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- KIF16B | c.1612+2T>C p.X538_splice | Splice Site (SNP) | VAF 18/76 reads (24%) | called by mutect2, varscan2
- KIR2DL3 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- MSH4 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NUGGC | c.527C>G p.T176R | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5K2 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OSBPL2 | c.123del p.N41Kfs*40 (on ENST00000313733 / NM_144498.4; = p.N29Kfs*40 on NM_014835.4) | Frame Shift Del (DEL) | VAF 32/151 reads (21%) | called by mutect2, pindel, varscan2
- SIMC1 | c.566C>A p.P189Q (on ENST00000443967 / NM_001308196.1; = p.P208Q on NM_001308195.2) | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- SUSD6 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TM2D3 | c.506A>G p.N169S (on ENST00000333202 / NM_078474.3; = p.N143S on NM_025141.3) | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TMPRSS2 | c.683+2T>C p.X228_splice | Splice Site (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- TRIP13 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- VDR | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 114/310 reads (37%) | called by muse, mutect2, varscan2
- ZNF266 | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | called by muse, varscan2
- ZNF560 | c.1561dup p.C521Lfs*27 | Frame Shift Ins (INS) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- ZNF671 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 436/586 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, varscan2
- ZWILCH | c.1638G>A p.W546* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- AHNAK2 | c.10275G>A p.A3425= | Silent (SNP) | VAF 242/607 reads (40%) | catalogued as rs770901235, COSV60931088; called by muse, mutect2, varscan2
- BCR | c.1437G>A p.S479= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs567775066, COSV59930323; called by muse, mutect2, varscan2
- CNTNAP5 | c.768C>A p.P256= | Silent (SNP) | VAF 71/171 reads (42%) | catalogued as COSV70471352; called by muse, mutect2, varscan2
- DNHD1 | c.6813C>T p.D2271= | Silent (SNP) | VAF 130/580 reads (22%) | catalogued as rs754762869; ClinVar: likely benign; called by muse, varscan2
- FAT4 | c.14922C>A p.P4974= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- IL21R | c.609G>A p.G203= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs755926054; ClinVar: likely benign; called by muse, mutect2, varscan2
- ISM1 | c.1323C>T p.N441= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as rs748892925, COSV52607711; called by muse, mutect2, varscan2
- KIF26A | c.2127C>T p.H709= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs370338382, COSV100181102; called by muse, mutect2, varscan2
- MMRN1 | c.2062C>T p.L688= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- OR14K1 | c.288G>A p.V96= | Silent (SNP) | VAF 198/408 reads (49%) | called by muse, mutect2, varscan2
- PAX8 | c.988T>C p.L330= | Silent (SNP) | VAF 107/284 reads (38%) | catalogued as rs1162523526; called by muse, mutect2, varscan2
- PPP1R9B | c.19C>A p.R7= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- TAF1L | c.1254C>T p.D418= | Silent (SNP) | VAF 104/292 reads (36%) | catalogued as rs757349383, COSV54257434; called by muse, mutect2, varscan2
- TERF2IP | c.1017T>C p.N339= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs781256024; called by muse, varscan2
- TSPEAR | c.162C>T p.H54= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs373833886; called by muse, mutect2, varscan2
- VPS54 | c.1659C>T p.S553= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as rs138163290; called by muse, mutect2, varscan2
- ZAN | c.8328C>T p.A2776= | Silent (SNP) | VAF 273/547 reads (50%) | catalogued as rs201777978; called by muse, mutect2, varscan2
- ZNF266 | c.1557C>G p.P519= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- ZNF266 | c.1347C>G p.S449= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, varscan2
- ZNF793 | c.132C>T p.L44= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs751530704; called by muse, mutect2, varscan2
- ADAMTS19 | c.1086+20C>T | Intron (SNP) | VAF 27/57 reads (47%) | catalogued as rs762566028; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501093 del TG | 5'Flank (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- GALNT9 | c.1077+7396C>T | Intron (SNP) | VAF 40/126 reads (32%) | catalogued as rs542289303; called by muse, mutect2, varscan2
- HLTF | c.2377-17C>T | Intron (SNP) | VAF 19/74 reads (26%) | catalogued as rs186474099; called by muse, mutect2, varscan2
- LINC01205 | n.183A>T | RNA (SNP) | VAF 74/199 reads (37%) | called by muse, mutect2, varscan2
- MYO1G | c.1949+88G>A | Intron (SNP) | VAF 26/625 reads (4%) | catalogued as rs762015453, COSV51855392; called by muse, mutect2
- SC5D | c.211-23del | Intron (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- SCUBE1 | c.*5475G>A | 3'UTR (SNP) | VAF 34/111 reads (31%) | catalogued as rs751815634; called by muse, mutect2, varscan2
- Unknown | chr7:55699078 G>C | IGR (SNP) | VAF 78/3511 reads (2%) | catalogued as rs1295027371; called by muse, mutect2
- ZNF541 | c.2797-26C>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- ZNF544 | c.244+4536C>T | Intron (SNP) | VAF 558/772 reads (72%) | called by muse, varscan2
